Somatic mutation profile of tumor specimen RC-B65Q-TBP1-A (aliquot RC-B65Q-TBP1-A-1-0-D-A93N-47) from RC case RC-B65Q, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.7 years (31,289 days).
Specimen RC-B65Q-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4baf01b0-b541-407e-9258-125a7129b1ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65Q-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65Q-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d000be7b-f21b-4dae-90a3-7202ba0cb3c1

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STXBP3 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.545); catalogued as COSV64181534; called by muse, mutect2
- CHAF1B | c.1535G>T p.S512I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LCA5L | c.1382T>C p.F461S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
